Gene-level copy-number profile of tumor specimen HCM-WCMC-0788-C34-01A from HCMI case HCM-WCMC-0788-C34, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Solid carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G3; Age at diagnosis: 72.6 years (26,516 days).
Specimen HCM-WCMC-0788-C34-01A: Sample type: Slides; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file cd37d78d-0ee3-47ab-b69f-567931c54ec3.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-WCMC-0788-C34-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,718 have no estimate.
https://portal.gdc.cancer.gov/files/c2406787-45e1-4570-a463-eea2d918df90

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 545; copy number 1: 13,433; copy number 2: 35,879; copy number 3: 8,767; copy number 4: 241; copy number 5: 13; copy number 7: 8; copy number 10: 9; copy number 12: 10.

Homozygous deletions (total copy number 0; autosomes only): 72 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:904,834–1,246,722, 33 genes: AL645608.6, AL645608.2, AL645608.4, LINC02593, SAMD11, NOC2L, KLHL17, PLEKHN1, PERM1, AL645608.7, HES4, ISG15, AL645608.3, AL645608.1, AGRN, AL645608.5, AL390719.1, AL645608.8, RNF223, C1orf159, AL390719.3, LINC01342, MIR200B, MIR200A, MIR429, AL390719.2, TTLL10-AS1, TTLL10, TNFRSF18, TNFRSF4, SDF4, B3GALT6, C1QTNF12.
- chr1:2,403,964–2,530,263, 6 genes (within-gene range 0–1): PEX10, PLCH2, AL139246.1, AL139246.4, PANK4, HES5.
- chr2:241,734,602–241,817,413, 7 genes (within-gene range 0–2): D2HGDH, AC114730.1, AC114730.2, GAL3ST2, AC131097.1, AC131097.2, NEU4.
- chr7:1,428,465–1,504,389, 4 genes: MICALL2, AC102953.1, AC102953.2, INTS1.
- chr8:31,275,542–31,598,204, 4 genes: AC068672.2, AC068672.3, AC068672.1, RNA5SP261.
- chr13:113,105,788–113,120,685, 1 gene: F7.
- chr14:34,740,336–34,740,833, 1 gene: RPL12P6.
- chr14:104,138,723–104,180,894, 1 gene: KIF26A.
- chr14:105,583,731–105,601,728, 2 genes: IGHA2, IGHE.
- chr14:105,621,116–105,621,180, 1 gene: MIR8071-1.
- chr16:88,382,959–88,537,031, 4 genes: ZNF469, ZFPM1, MIR5189, AC116552.1.
- chr17:3,923,870–3,964,464, 1 gene: ATP2A3.
- chr21:44,978,832–45,004,727, 4 genes: AP001505.1, LINC00163, LINC00165, PICSAR.
- chr22:18,906,028–18,947,732, 3 genes (within-gene range 0–4): DGCR6, AC007326.4, PRODH.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 40 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:145,052,465–145,066,685, 1 gene, copy number 5: C8orf33.
- chr16:33,769,421–33,859,352, 10 genes, copy number 12: ENPP7P13, AC136428.2, IGHV3OR16-12, AC136428.3, IGHV3OR16-13, AC136428.1, AC140658.6, AC140658.7, AC140658.2, IGHV3OR16-11.
- chr16:34,015,260–34,163,110, 9 genes, copy number 10: AC133561.4, AC133561.3, AC136932.1, DUX4L45, PCMTD1P2, DUX4L46, DUX4L47, LINC00273, RNA5-8SP2.
- chr19:58,513,530–58,605,223, 12 genes, copy number 5: ZBTB45, RN7SL525P, TRIM28, MIR6807, CHMP2A, UBE2M, MZF1-AS1, MZF1, CENPBD1P1, AC016629.3, AC016629.1, AC016629.2.
- chr21:8,603,547–8,603,984, 1 gene, copy number 7: RPSAP68.
- chr22:18,773,665–18,894,407, 7 genes, copy number 7: GGT3P, AC008132.2, E2F6P1, AC008132.1, BCRP7, FAM230F, AC008103.1.

Autosomal genes at a single copy (total copy number 1): 11,072. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
